Somatic mutation profile of tumor specimen TCGA-BG-A0YV-01A (aliquot TCGA-BG-A0YV-01A-11D-A10M-09) from TCGA case TCGA-BG-A0YV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 67.3 years (24,567 days).
Specimen TCGA-BG-A0YV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d867c7a-ea02-48b7-9150-cb1a78d7ce83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0YV-10A (Blood Derived Normal), aliquot TCGA-BG-A0YV-10A-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58f872b3-378a-4781-8ca6-8f2f0154eace

The open-access MAF lists 85 somatic variants for this specimen: 65 protein-altering or splice-affecting, 14 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 14, Nonsense Mutation 4, Intron 3, Frame Shift Del 3, 3'UTR 1, Splice Site 1, 3'Flank 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.634+3_634+6del p.X212_splice | Splice Site (DEL) | VAF 43/93 reads (46%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 108/122 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABAT | c.725A>T p.D242V | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV51620888; called by muse, mutect2, varscan2
- ACAP1 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 109/124 reads (88%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs192044976; called by muse, mutect2, varscan2
- ANKRD50 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs376403231, COSV72385179; called by muse, mutect2, varscan2
- ANO7 | c.1361G>A p.C454Y (on ENST00000274979; = p.C400Y on NM_001370694.2) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51469029, COSV51478185; called by muse, mutect2, varscan2
- ARID1A | c.4225C>T p.Q1409* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV61372846; called by muse, mutect2, varscan2
- ATR | c.1645A>G p.S549G | Missense Mutation (SNP) | VAF 60/240 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.01); catalogued as COSV100637679, COSV63384593; called by muse, mutect2, varscan2
- C8orf74 | c.759G>T p.Q253H | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58753595, COSV58755560; called by muse, mutect2
- CIC | c.4249C>T p.R1417C | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs778167932, COSV50549090; called by muse, mutect2, varscan2
- CNTNAP2 | c.1126G>A p.V376I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.022); catalogued as COSV62150650; called by muse, mutect2, varscan2
- CR1 | c.5942C>T p.T1981M | Missense Mutation (SNP) | VAF 57/282 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs768897573, COSV65456372; called by muse, mutect2, varscan2
- CSMD3 | c.4432A>C p.N1478H (on ENST00000297405 / NM_001363185.1; = p.N1374H on NM_052900.3) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV52116125; called by muse, mutect2, varscan2
- CXCL5 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as COSV56018333; called by muse, mutect2, varscan2
- DHX29 | c.3272T>A p.I1091K | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52416902, COSV99287452; called by muse, mutect2, varscan2
- DOC2A | c.1107G>C p.W369C | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58750702; called by muse, mutect2
- EPHA5 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs369606981, COSV56635227; called by muse, mutect2, varscan2
- FAM9A | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 80/262 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.801); catalogued as COSV66812994, COSV66813082; called by muse, mutect2, varscan2
- FASTKD5 | c.1985C>G p.A662G | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.44); PolyPhen benign (0.339); catalogued as COSV53904491; called by muse, mutect2, varscan2
- FAT4 | c.13934G>A p.R4645H | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs147961375; called by muse, mutect2, varscan2
- FBXO24 | c.620G>A p.R207Q (on ENST00000241071 / NM_033506.3; = p.R245Q on NM_012172.5) | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); catalogued as rs750143520, COSV53824226, COSV99575820; called by muse, mutect2, varscan2
- GABRA6 | c.660T>G p.I220M | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV50877970; called by muse, mutect2, varscan2
- HIPK2 | c.2546C>T p.P849L | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs760156592, COSV61226082; called by muse, mutect2, varscan2
- HNRNPF | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100563338, COSV61560648; called by muse, mutect2, varscan2
- ITGA11 | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs377444249; called by muse, mutect2, varscan2
- ITGB2 | c.2282G>A p.R761H (on ENST00000302347; = p.R737H on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs138714119; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITIH1 | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs200097012, COSV56252839; called by muse, mutect2, varscan2
- KCND3 | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs1483590521, COSV56174041; called by muse, mutect2
- KRT80 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs768758448, COSV57547833; called by muse, mutect2, varscan2
- KRTAP10-5 | c.376T>C p.C126R | Missense Mutation (SNP) | VAF 67/279 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV59953980; called by muse, mutect2, varscan2
- LRRIQ1 | c.3841G>A p.A1281T | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs772833824, COSV67826790; called by muse, mutect2, varscan2
- MAGEC2 | c.741G>T p.E247D | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV55998197, COSV56000073; called by muse, mutect2, varscan2
- MAP2 | c.3913G>T p.G1305W | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52283165; called by muse, mutect2, varscan2
- MARK1 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as rs201557089; called by muse, mutect2, varscan2
- MEI1 | c.2553C>G p.I851M | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV55901257; called by muse, mutect2, varscan2
- MYNN | c.529T>C p.S177P | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.91); catalogued as rs1242858317, COSV62990991; called by muse, mutect2, varscan2
- MYO1D | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs747181107, COSV59008314; called by muse, mutect2, varscan2
- NOS3 | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.871); catalogued as rs765572803, COSV52486913; called by muse, mutect2, varscan2
- NTRK1 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs770090356, COSV62323889; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUCKS1 | c.18A>C p.R6S | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as COSV63347806; called by muse, mutect2, varscan2
- OBSCN | c.7316G>T p.R2439L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.695); catalogued as COSV52747662; called by muse, mutect2, varscan2
- OR6C1 | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.031); catalogued as COSV65572791; called by muse, mutect2, varscan2
- OTOF | c.2419C>T p.Q807* (on ENST00000272371 / NM_194248.3; = p.Q60* on NM_004802.4) | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV55497449; called by muse, mutect2, varscan2
- OTUD6A | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV57972732, COSV57973745; called by muse, mutect2, varscan2
- PALLD | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.703); catalogued as COSV54974488; called by muse, mutect2
- PATJ | c.1040C>G p.P347R | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs779314951, COSV57156774; called by muse, mutect2, varscan2
- PCDHB14 | c.1074G>T p.E358D | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53386881; called by muse, mutect2, varscan2
- PDZD2 | c.7013G>A p.R2338Q | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771714123, COSV56852499; called by muse, mutect2, varscan2
- PLXNB2 | c.3428C>T p.T1143M | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs1443835685, COSV63780333; called by muse, mutect2, varscan2
- PPIL4 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 49/165 reads (30%) | catalogued as rs1296278642, COSV53566367, COSV53569053; called by muse, mutect2, varscan2
- PTPN13 | c.3274A>G p.T1092A (on ENST00000411767 / NM_080683.3; = p.T1073A on NM_006264.3) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV57403439; called by muse, mutect2, varscan2
- PTTG2 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1479830100, COSV54715017; called by muse, mutect2, varscan2
- RGS22 | c.3374G>T p.G1125V | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV62658159; called by muse, mutect2, varscan2
- ROGDI | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 54/111 reads (49%) | catalogued as COSV58925864; called by muse, mutect2, varscan2
- RXFP2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 24/91 reads (26%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV53633546; called by muse, mutect2, varscan2
- WWP1 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 64/118 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.101); catalogued as COSV55356901; called by muse, mutect2, varscan2
- ZBTB37 | c.552C>G p.I184M | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as rs780322588, COSV62931560; called by muse, mutect2, varscan2
- ZBTB7C | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 51/225 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs768320795, COSV59687844; called by muse, mutect2, varscan2
- ZNF142 | c.5399G>A p.R1800H (on ENST00000411696 / NM_001379660.1; = p.R1600H on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs200894546, COSV68742867, COSV68743077; called by muse, mutect2, varscan2
- ZNF7 | c.1081C>A p.P361T | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV57382796; called by muse, mutect2, varscan2
- ZNF713 | c.1190G>A p.S397N (on ENST00000633730 / NM_001366796.2; = p.S410N on NM_182633.3) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.604); catalogued as COSV70056441; called by muse, mutect2, varscan2
- ZNF792 | c.1362G>T p.E454D | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1235032494, COSV68692827; called by muse, mutect2, varscan2
- CTCF | c.1280del p.L427Yfs*20 | Frame Shift Del (DEL) | VAF 53/142 reads (37%) | called by mutect2, pindel, varscan2
- PTEN | c.258_260delinsCC p.Q87Hfs*12 | Frame Shift Del (DEL) | VAF 61/166 reads (37%) | called by pindel, varscan2*
- VPS11 | c.715_716del p.S239Pfs*7 (on ENST00000620429; = p.S783Pfs*7 on NM_021729.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 35/74 reads (47%) | called by pindel, varscan2
- ABCB5 | c.1722G>A p.R574= (on ENST00000404938 / NM_001163941.2; = p.R129= on NM_178559.6) | Silent (SNP) | VAF 112/208 reads (54%) | catalogued as COSV51704184; called by muse, mutect2
- ANXA8L1 | c.546C>T p.D182= | Silent (SNP) | VAF 117/359 reads (33%) | catalogued as rs1325400874; called by muse, mutect2, varscan2
- BAZ2A | c.2637G>A p.L879= | Silent (SNP) | VAF 42/73 reads (58%) | catalogued as COSV51632716; called by muse, mutect2, varscan2
- CD82 | c.153G>A p.S51= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as rs777966335, COSV57034086; called by muse, mutect2, varscan2
- GRM7 | c.243G>A p.A81= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV63131913; called by muse, mutect2, varscan2
- HIGD1B | c.45C>T p.D15= | Silent (SNP) | VAF 25/129 reads (19%) | catalogued as COSV53655231; called by muse, mutect2, varscan2
- KCNA1 | c.93C>T p.D31= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs375647671; called by muse, mutect2, varscan2
- KIT | c.153C>T p.G51= | Silent (SNP) | VAF 41/128 reads (32%) | catalogued as rs147363921, COSV55390842, COSV55430694; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- KRI1 | c.972G>A p.K324= | Silent (SNP) | VAF 56/408 reads (14%) | catalogued as COSV57263786; called by muse, mutect2, varscan2
- LRRK2 | c.2143A>C p.R715= | Silent (SNP) | VAF 25/138 reads (18%) | catalogued as COSV54146053; called by muse, mutect2, varscan2
- PCDHA2 | c.1131C>T p.R377= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV65365267; called by muse, mutect2, varscan2
- PRDM9 | c.1389G>A p.L463= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as COSV57003377, COSV57014394; called by muse, mutect2, varscan2
- SMG1 | c.4443C>T p.P1481= | Silent (SNP) | VAF 81/180 reads (45%) | catalogued as rs757900422, COSV67169768; called by muse, mutect2, varscan2
- ZACN | c.486C>T p.L162= | Silent (SNP) | VAF 36/70 reads (51%) | catalogued as COSV100135535, COSV58035181; called by muse, mutect2
- FGFR3 | c.*1417C>T | 3'UTR (SNP) | VAF 10/17 reads (59%) | catalogued as rs754239704, COSV53393902; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.788T>A | RNA (SNP) | VAF 158/274 reads (58%) | called by muse, mutect2, varscan2
- RNF145 | c.-40+1464A>T | Intron (SNP) | VAF 80/290 reads (28%) | catalogued as rs148563155, COSV50864655; called by muse, mutect2, varscan2
- RNF145 | c.-40+1463T>G | Intron (SNP) | VAF 80/290 reads (28%) | catalogued as COSV50864669; called by muse, mutect2, varscan2
- RUSC1 | c.-86-232C>T | Intron (SNP) | VAF 5/28 reads (18%) | catalogued as rs558585105, COSV52738410; called by muse, mutect2
- YPEL4 | chr11:57641279 G>A | 3'Flank (SNP) | VAF 33/89 reads (37%) | catalogued as rs780920884; called by muse, mutect2, varscan2
